Somatic mutation profile of tumor specimen TCGA-OR-A5LK-01A (aliquot TCGA-OR-A5LK-01A-11D-A29I-10) from TCGA case TCGA-OR-A5LK, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 62.7 years (22,919 days).
Specimen TCGA-OR-A5LK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1239a1db-7491-46e1-8f2f-8793cd1d9f0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5LK-10A (Blood Derived Normal), aliquot TCGA-OR-A5LK-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c99a44ba-6b2b-4e8b-98b1-f3f8b40f044c

The open-access MAF lists 38 somatic variants for this specimen: 28 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 27, Silent 10, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 33/164 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CHRNB3 | c.375C>A p.F125L | Missense Mutation (SNP) | VAF 58/100 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51494803, COSV99251439; called by muse, mutect2, varscan2
- CKM | c.538A>G p.T180A | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as rs1555769406; called by muse, mutect2, varscan2
- HSPG2 | c.5681C>T p.T1894M | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as rs151035968; called by muse, mutect2, varscan2
- PPEF1 | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1480343562, COSV62995001; called by muse, mutect2, varscan2
- PTPRN2 | c.3004G>A p.V1002M | Missense Mutation (SNP) | VAF 19/264 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs138836883; called by muse, mutect2
- SORL1 | c.5790C>G p.D1930E | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.446); catalogued as rs1565357143; called by muse, mutect2, varscan2
- SYNE1 | c.391C>A p.L131I (on ENST00000367255 / NM_182961.4; = p.L138I on NM_033071.3) | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55072315; called by muse, mutect2, varscan2
- TNR | c.1058C>T p.T353M | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs138654492; called by muse, mutect2, varscan2
- TRIM42 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV53883578; called by muse, mutect2
- ZNF761 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs779549000, COSV61888162; called by muse, mutect2, varscan2
- ABCD2 | c.775C>A p.L259I | Missense Mutation (SNP) | VAF 78/243 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- ABLIM3 | c.1398C>G p.S466R | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM2 | c.962T>A p.I321N | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ARHGAP35 | c.3911A>G p.N1304S | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0); called by mutect2, varscan2
- FBN2 | c.517A>T p.T173S | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- FMN1 | c.3893C>A p.P1298H (on ENST00000616417 / NM_001277313.2; = p.P1075H on NM_001103184.4) | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HMCN1 | c.12375G>C p.Q4125H | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- MAGEB6B | c.1196T>A p.V399E | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- MUL1 | c.310A>G p.N104D | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYLK2 | c.1411A>C p.I471L | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2
- OR10S1 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5H14 | c.911T>C p.M304T | Missense Mutation (SNP) | VAF 19/209 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- RAPGEF2 | c.4105A>G p.T1369A | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM48 | c.1017+1G>T p.X339_splice | Splice Site (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2, varscan2
- SCUBE2 | c.295G>T p.V99F | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEC24A | c.1598T>A p.L533Q | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- XAB2 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ATRNL1 | c.198C>A p.T66= | Silent (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- GDF9 | c.1251G>A p.P417= | Silent (SNP) | VAF 13/208 reads (6%) | catalogued as rs779083274, COSV51526680; called by muse, mutect2
- GRID2 | c.1551C>T p.A517= | Silent (SNP) | VAF 19/134 reads (14%) | catalogued as rs560303075, COSV56190911, COSV56287917; called by mutect2, varscan2
- LAMA1 | c.3348G>A p.G1116= | Silent (SNP) | VAF 13/175 reads (7%) | catalogued as rs764989664; called by muse, mutect2
- LIMK2 | c.1350G>A p.R450= | Silent (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- MAP3K5 | c.3018A>G p.G1006= | Silent (SNP) | VAF 7/174 reads (4%) | called by muse, mutect2
- PXDNL | c.2436C>T p.H812= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs1453645611, COSV62491694; called by muse, mutect2
- TRAFD1 | c.1704C>G p.S568= | Silent (SNP) | VAF 6/110 reads (5%) | catalogued as COSV99986896; called by muse, mutect2
- TRRAP | c.9189G>C p.R3063= (on ENST00000359863 / NM_001244580.1; = p.R3034= on NM_003496.3) | Silent (SNP) | VAF 16/202 reads (8%) | called by muse, mutect2
- ZNF628 | c.2598G>A p.Q866= | Silent (SNP) | VAF 63/187 reads (34%) | catalogued as rs747362459; called by muse, mutect2, varscan2
